FM case AD4496 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/30738f2a-c822-433e-80ca-8daad9c152ab

Female, 61.6 years: Carcinoma, NOS (ICD-O-3 8010/3) of the pancreas; primary biopsied or resected from the pancreas. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
